Somatic mutation profile of tumor specimen MMRF_1257_1_BM_CD138pos (aliquot MMRF_1257_1_BM_CD138pos_T2_TSE61_K03602) from MMRF case MMRF_1257, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.9 years (27,355 days).
Specimen MMRF_1257_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecc8751a-5103-4dc7-8fc2-8bf3e6a2e8a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1257_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1257_1_PB_Whole_C1_TSE61_K03601; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/492879e5-d16a-4401-933d-4fcb86cc79ab

The open-access MAF lists 107 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 36, Silent 16, 5'UTR 3, Intron 3, Frame Shift Del 3, RNA 3, 5'Flank 2, Nonsense Mutation 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 44/98 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0.398); catalogued as rs1170730852; called by muse, mutect2, varscan2
- ACE | c.2806G>A p.V936M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs752081336, COSV52003930, COSV52013949; called by muse, mutect2, varscan2
- ACVR1B | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328289074, COSV57779851; called by muse, mutect2, varscan2
- BAG3 | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV64842062; called by muse, mutect2
- CAPN9 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs141682829; called by muse, mutect2, varscan2
- CEACAM16 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs369526797; called by muse, mutect2, varscan2
- CNTNAP3 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as rs767541305, COSV52666529; called by muse, mutect2, varscan2
- CXADR | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 66/114 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242288001, COSV53031593; called by muse, mutect2, varscan2
- DLGAP1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs773388283; called by muse, mutect2, varscan2
- DZIP3 | c.3191A>G p.Y1064C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1226905016; called by muse, mutect2, varscan2
- GCKR | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs755324662, COSV53106701; called by muse, mutect2, varscan2
- KIF26A | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs772147308, COSV59468723; called by muse, mutect2, varscan2
- MOB3A | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs201134829, COSV63865489; called by muse, mutect2, varscan2
- PGK2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV59162902; called by muse, mutect2
- TCL1A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs79966636; called by muse, mutect2, varscan2
- ADGRL2 | c.1035T>G p.N345K | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRV1 | c.18267G>A p.W6089* | Nonsense Mutation (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- B3GNT3 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAST | c.111A>C p.K37N | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- DBF4 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DCC | c.2391A>C p.K797N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTF3C4 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- HCN4 | c.3156G>C p.L1052F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LRIG2 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MEOX2 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO16 | c.3636C>G p.D1212E | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- NEB | c.13726A>G p.T4576A | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OLR1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR9A4 | c.939G>T p.R313S | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, varscan2
- PDE9A | c.770_771del p.R257Qfs*5 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | called by mutect2, pindel*, varscan2*
- PTPN21 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP2 | c.7676A>C p.E2559A | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RUBCN | c.2435T>A p.L812Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SATL1 | c.211C>A p.Q71K (on ENST00000395409; = p.Q258K on NM_001012980.2) | Missense Mutation (SNP) | VAF 62/63 reads (98%) | SIFT tolerated (0.28); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- SYNM | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 66/87 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TAS2R46 | c.510del p.S170Rfs*10 | Frame Shift Del (DEL) | VAF 68/154 reads (44%) | called by mutect2, pindel, varscan2
- TCERG1 | c.2174del p.I725Kfs*11 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | called by mutect2, pindel, varscan2
- TENM3 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TMTC1 | c.1532A>C p.K511T (on ENST00000539277 / NM_001193451.2; = p.K403T on NM_175861.3) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TNFSF11 | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- URB1 | c.3521T>C p.L1174P | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF577 | c.224T>G p.L75W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AC131160.1 | c.384C>A p.V128= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- ANO1 | c.2409C>T p.F803= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs755573888; called by muse, mutect2, varscan2
- BPTF | c.606C>T p.S202= | Silent (SNP) | VAF 31/42 reads (74%) | called by muse, mutect2, varscan2
- FBXL17 | c.1224A>G p.A408= | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- H2AX | c.426G>A p.E142= | Silent (SNP) | VAF 80/127 reads (63%) | called by muse, mutect2, varscan2
- ITPRIPL2 | c.996G>A p.A332= | Silent (SNP) | VAF 48/102 reads (47%) | called by muse, mutect2, varscan2
- KCNG1 | c.309C>T p.N103= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV65368714; called by muse, mutect2, varscan2
- KRT6B | c.594G>T p.L198= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2, varscan2
- LTB | c.234G>A p.E78= | Silent (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- MNS1 | c.963A>G p.Q321= | Silent (SNP) | VAF 168/234 reads (72%) | catalogued as COSV53068244; called by muse, mutect2, varscan2
- NCCRP1 | c.84G>A p.S28= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1469638041; called by muse, mutect2, varscan2
- PROCR | c.138C>A p.G46= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- SLC18A2 | c.753G>A p.P251= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs926621814, COSV53690253; called by muse, mutect2, varscan2
- TYRP1 | c.1098G>A p.T366= | Silent (SNP) | VAF 73/105 reads (70%) | catalogued as rs541742268, COSV66358149, COSV66358583; called by muse, mutect2, varscan2
- ZDHHC11 | c.984C>T p.F328= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV52074482; called by muse, mutect2, varscan2
- ZNF395 | c.393T>C p.C131= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60428705; called by muse, mutect2, varscan2
- ADAM5 | n.235G>A | RNA (SNP) | VAF 25/33 reads (76%) | catalogued as rs921773139; called by muse, mutect2, varscan2
- AGMO | c.*895C>A | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- AL592490.1 | c.*1350T>G | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- AP000944.4 | n.30G>A | RNA (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- ASB1 | c.*2932C>T | 3'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- ATP11C | c.*1045G>A | 3'UTR (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- ATP8B4 | c.*1953G>T | 3'UTR (SNP) | VAF 27/70 reads (39%) | catalogued as rs1238199274; called by muse, varscan2
- BEST1 | chr11:61950327 T>G | 5'Flank (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- BMP6 | c.*804A>G | 3'UTR (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- C17orf107 | c.*31T>C | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- CHRNA7 | c.*394A>C | 3'UTR (SNP) | VAF 50/260 reads (19%) | called by muse, varscan2
- CYP20A1 | c.*3401A>C | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- DRAIC | n.428C>A | RNA (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ELP4 | chr11:31787038 ins AATG | 3'Flank (INS) | VAF 35/80 reads (44%) | called by mutect2, varscan2
- EMX2 | c.*515T>C | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- KLK3 | c.631-220A>G | Intron (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- LDOC1 | c.*143A>C | 3'UTR (SNP) | VAF 40/41 reads (98%) | called by muse, mutect2, varscan2
- LGI2 | c.*766_*774del | 3'UTR (DEL) | VAF 63/139 reads (45%) | called by mutect2, pindel, varscan2
- LMF1 | c.*249C>T | 3'UTR (SNP) | VAF 47/78 reads (60%) | called by muse, mutect2, varscan2
- MGAT2 | c.*222T>G | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- NXPE3 | c.-498+344G>C | Intron (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- OTUD7A | c.*27G>A | 3'UTR (SNP) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- PLPPR4 | c.*882T>C | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- POT1 | c.*685A>C | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- PPP1R12A | c.*650T>G | 3'UTR (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- PRKRA | c.*356C>A | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- PRR16 | c.*412C>A | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- PSMD14 | c.-223G>A | 5'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- RALA | c.-174C>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- RASA3 | c.*1385G>A | 3'UTR (SNP) | VAF 43/58 reads (74%) | catalogued as rs1392445832; called by muse, mutect2, varscan2
- SLCO1A2 | c.*943G>T | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- SP140L | c.*170C>G | 3'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- SPSB1 | c.*1536del | 3'UTR (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel
- SRD5A3 | c.*864T>C | 3'UTR (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- SYT4 | c.*118T>G | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- TAF1L | c.*244G>A | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs993029518; called by muse, mutect2
- TMEM176A | chr7:150800421 C>T | 5'Flank (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- TNRC18 | c.*1303T>C | 3'UTR (SNP) | VAF 32/111 reads (29%) | catalogued as rs1468982297; called by muse, mutect2, varscan2
- TSPAN9 | c.*3112T>A | 3'UTR (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*513A>G | 3'UTR (SNP) | VAF 33/78 reads (42%) | catalogued as rs961604844; called by muse, mutect2, varscan2
- WDR24 | c.184+74C>T | Intron (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- WDTC1 | c.*274C>A | 3'UTR (SNP) | VAF 86/158 reads (54%) | called by muse, mutect2, varscan2
- ZFP36 | c.*119_*120del | 3'UTR (DEL) | VAF 21/118 reads (18%) | called by mutect2, pindel, varscan2
- ZIC1 | c.*1770A>C | 3'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ZNF366 | c.*344A>C | 3'UTR (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- ZNF559 | c.-51C>A | 5'UTR (SNP) | VAF 18/78 reads (23%) | catalogued as COSV57837227; called by muse, mutect2, varscan2
- ZNF681 | c.*42T>A | 3'UTR (SNP) | VAF 62/186 reads (33%) | called by muse, mutect2, varscan2
- ZYX | c.*253C>A | 3'UTR (SNP) | VAF 12/96 reads (13%) | called by mutect2, varscan2
